Somatic mutation profile of tumor specimen C3L-00017-02 (aliquot CPT0000250005_1) from CPTAC case C3L-00017, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.4 years (25,349 days).
Specimen C3L-00017-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a4953e7-ebdf-4766-bb40-3bec7387a744.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00017-31 (Blood Derived Normal), aliquot CPT0000580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b3f6113-26c9-4ff1-ac01-aa7eb4a996c9

The open-access MAF lists 88 somatic variants for this specimen: 50 protein-altering or splice-affecting, 25 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 25, Intron 9, Nonsense Mutation 2, 5'UTR 2, 3'UTR 1, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 77/439 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs765339011, COSV63660350; called by muse, mutect2, varscan2
- ARHGAP9 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 98/704 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs145403284; called by muse, mutect2, varscan2
- ASMT | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 83/1234 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs121918820, CM110486; called by muse, mutect2
- CDH7 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs761625164; called by muse, mutect2, varscan2
- CILP | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758135189; called by muse, mutect2, varscan2
- COL16A1 | c.2431C>T p.R811W | Missense Mutation (SNP) | VAF 69/454 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs376617047; called by muse, mutect2, varscan2
- DNAH9 | c.12059C>T p.T4020M | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs774626535; called by muse, mutect2, varscan2
- DRD5 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV58577739; called by muse, mutect2, varscan2
- EHBP1 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs750441921, COSV99859654; called by muse, mutect2, varscan2
- HCAR2 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 110/724 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs775536264, COSV100186705; called by muse, mutect2, varscan2
- HRH3 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs779379623; called by muse, mutect2, varscan2
- HTR2C | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs782383804, COSV52201784; called by muse, mutect2, varscan2
- IGLON5 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 88/577 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1171901550, COSV54536450; called by muse, mutect2, varscan2
- ITGAX | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs146081281; called by muse, mutect2, varscan2
- KDM5C | c.4636C>T p.R1546W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.18); catalogued as rs782154592; called by muse, mutect2, varscan2
- MARCHF11 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV60128391; called by muse, mutect2, varscan2
- MDGA2 | c.2440G>C p.E814Q (on ENST00000399232 / NM_001113498.2; = p.E516Q on NM_182830.4) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV62084060; called by muse, mutect2, varscan2
- MYH13 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as rs751347030; called by muse, mutect2, varscan2
- NINL | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as rs1226207687, COSV54000699; called by muse, mutect2, varscan2
- PAX6 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 91/731 reads (12%) | catalogued as COSV53792782; called by muse, mutect2, varscan2
- PRR5L | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237970347, COSV100286809; called by muse, mutect2, varscan2
- RBFOX1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.036); catalogued as rs749566543, COSV60983781; called by muse, mutect2, varscan2
- RYR3 | c.11195G>A p.R3732H (on ENST00000389232; = p.R3733H on NM_001036.6) | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs374140172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.083); catalogued as rs771897021, COSV51455032; called by muse, mutect2, varscan2
- SEMA5A | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs754065909, COSV66785353; called by muse, mutect2, varscan2
- TAF1L | c.2524C>T p.R842W | Missense Mutation (SNP) | VAF 136/1101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220675404, COSV54267869; called by muse, mutect2, varscan2
- TEP1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs769367433, COSV52987297, COSV52993929; called by muse, mutect2, varscan2
- TIAM1 | c.3654C>T p.D1218= | Splice Region (SNP) | VAF 21/243 reads (9%) | catalogued as rs375189386; called by muse, mutect2
- TMEM63A | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs753018849; called by muse, mutect2, varscan2
- TSC2 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs760489473, CD982984, COSV54782931; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TSGA13 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs782369380, COSV58406542; called by muse, mutect2, varscan2
- WIPF3 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs755603892, COSV54208225; called by muse, mutect2
- ZNF549 | c.1025G>A p.R342H (on ENST00000376233 / NM_001199295.2; = p.R329H on NM_153263.2) | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as rs374746805; called by muse, mutect2, varscan2
- DES | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIXDC1 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FMN2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 201/540 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FOLR1 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 106/631 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HERC1 | c.2084G>T p.G695V | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.2792A>T p.Q931L | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- OR51Q1 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR6N1 | c.118T>A p.L40M | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.121); called by muse, mutect2
- RACK1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RTCB | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RTCB | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 78/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SMO | c.2022G>T p.K674N | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SPECC1L | c.359G>C p.S120T | Missense Mutation (SNP) | VAF 112/533 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, varscan2
- TP53 | c.701_730del p.Y234_G244delinsC | In Frame Del (DEL) | VAF 72/550 reads (13%) | called by mutect2, pindel
- TRIM28 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 79/482 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TTC22 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANKZF1 | c.1657C>T p.L553= | Silent (SNP) | VAF 41/230 reads (18%) | catalogued as rs113918917; called by muse, mutect2, varscan2
- ASTN1 | c.432G>A p.S144= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as rs778838558, COSV56067931; called by muse, mutect2, varscan2
- B4GALNT4 | c.1032C>T p.C344= | Silent (SNP) | VAF 52/463 reads (11%) | catalogued as rs1035639538, COSV100327087, COSV57323866; called by muse, mutect2, varscan2
- COL6A6 | c.471C>T p.D157= | Silent (SNP) | VAF 54/379 reads (14%) | catalogued as rs748065583, COSV62019101; called by muse, mutect2, varscan2
- IRX4 | c.453C>T p.R151= | Silent (SNP) | VAF 52/313 reads (17%) | catalogued as COSV51472689; called by muse, mutect2, varscan2
- ITLN1 | c.390G>A p.T130= | Silent (SNP) | VAF 152/746 reads (20%) | catalogued as rs202028015; called by muse, mutect2, varscan2
- JAK2 | c.1047T>G p.G349= | Silent (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- KANSL1 | c.2463C>T p.P821= | Silent (SNP) | VAF 51/305 reads (17%) | catalogued as rs765044321; called by muse, mutect2, varscan2
- KCNJ9 | c.708C>T p.D236= | Silent (SNP) | VAF 88/835 reads (11%) | catalogued as rs1219111247, COSV63631533; called by muse, mutect2, varscan2
- LRRC27 | c.627G>A p.A209= | Silent (SNP) | VAF 35/310 reads (11%) | catalogued as rs758352841, COSV59806984; called by muse, mutect2, varscan2
- MAGEL2 | c.1221G>A p.P407= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1315124369; ClinVar: likely benign; called by muse, mutect2, varscan2
- MST1R | c.3171C>A p.I1057= | Silent (SNP) | VAF 55/997 reads (6%) | catalogued as COSV99619044; called by muse, mutect2
- MYO1H | c.111G>A p.A37= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs548292658, COSV60451628; called by muse, mutect2, varscan2
- PARP4 | c.4944A>G p.K1648= | Silent (SNP) | VAF 52/227 reads (23%) | called by muse, mutect2, varscan2
- PLCB1 | c.2637C>A p.L879= | Silent (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- POTEE | c.237C>T p.N79= | Silent (SNP) | VAF 158/1258 reads (13%) | catalogued as rs766031955, COSV58226185, COSV58233405; called by muse, mutect2, varscan2
- SLC8A1 | c.993G>A p.K331= | Silent (SNP) | VAF 54/509 reads (11%) | called by muse, mutect2, varscan2
- SPOCK1 | c.12C>T p.I4= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as rs779124569; called by muse, mutect2, varscan2
- STARD9 | c.12117G>A p.P4039= | Silent (SNP) | VAF 86/433 reads (20%) | catalogued as rs922143606; called by muse, mutect2, varscan2
- TP73 | c.1374C>T p.H458= | Silent (SNP) | VAF 51/310 reads (16%) | catalogued as rs762610584; called by muse, mutect2, varscan2
- TPO | c.156C>T p.T52= | Silent (SNP) | VAF 116/870 reads (13%) | catalogued as rs770575352; called by muse, mutect2, varscan2
- TTN | c.19416G>A p.P6472= (on ENST00000591111; = p.P5545= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs368422028; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBB | c.466C>A p.R156= | Silent (SNP) | VAF 43/313 reads (14%) | catalogued as rs1208752776; called by muse, mutect2, varscan2
- UNCX | c.1158G>T p.P386= | Silent (SNP) | VAF 43/294 reads (15%) | called by muse, varscan2
- ZBTB16 | c.1398C>T p.C466= | Silent (SNP) | VAF 103/760 reads (14%) | catalogued as rs116547293, COSV60091982; called by muse, mutect2, varscan2
- ABCC13 | n.3698A>C | RNA (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- ADCYAP1 | c.-47C>T | 5'UTR (SNP) | VAF 25/204 reads (12%) | catalogued as rs1482939593, COSV52486777; called by muse, mutect2, varscan2
- CYTH3 | c.449+768T>C | Intron (SNP) | VAF 41/138 reads (30%) | called by muse, mutect2, varscan2
- G2E3 | c.-5+1489T>C | Intron (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- ITGAM | c.2711+28del | Intron (DEL) | VAF 45/313 reads (14%) | called by mutect2, pindel, varscan2
- KLHL7 | c.*154G>A | 3'UTR (SNP) | VAF 43/556 reads (8%) | called by muse, mutect2
- LLGL2 | c.2954-10C>T | Intron (SNP) | VAF 47/362 reads (13%) | catalogued as rs905470975; called by muse, mutect2, varscan2
- PLEKHH1 | c.3933+319C>T | Intron (SNP) | VAF 47/464 reads (10%) | called by muse, mutect2
- PTPRQ | c.19+1200C>G | Intron (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2
- SLC49A3 | c.586-34C>T | Intron (SNP) | VAF 29/214 reads (14%) | catalogued as rs755977183; called by muse, mutect2, varscan2
- SLC4A8 | c.-112+11722G>T | Intron (SNP) | VAF 40/255 reads (16%) | catalogued as rs1035815367; called by muse, mutect2, varscan2
- TXNDC16 | c.-25C>T | 5'UTR (SNP) | VAF 51/360 reads (14%) | catalogued as rs756680917; called by muse, mutect2, varscan2
- WT1 | c.1063-22T>A | Intron (SNP) | VAF 95/652 reads (15%) | called by muse, mutect2, varscan2
